Somatic mutation profile of tumor specimen TCGA-06-A5U1-01A (aliquot TCGA-06-A5U1-01A-11D-A33T-08) from TCGA case TCGA-06-A5U1, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Occipital lobe; Age at diagnosis: 78.2 years (28,545 days).
Specimen TCGA-06-A5U1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf3c4984-1429-4b37-9c47-8d8b9b9833fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-A5U1-10A (Blood Derived Normal), aliquot TCGA-06-A5U1-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a007aab-6c65-4cbc-8ffb-9385e91a4e78

The open-access MAF lists 79 somatic variants for this specimen: 48 protein-altering or splice-affecting, 30 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 30, Nonsense Mutation 5, Frame Shift Del 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRLF2 | c.383C>T p.S128L | Missense Mutation (SNP) | VAF 52/140 reads (37%) | hotspot (GDC flag); SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1319865856, COSV67493811; called by muse, mutect2, varscan2
- SLC6A1 | c.650C>T p.T217M | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1396036517, COSV99822786; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS20 | c.2060G>C p.C687S | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101239367; called by muse, mutect2, varscan2
- APOB | c.1861G>T p.E621* | Nonsense Mutation (SNP) | VAF 34/135 reads (25%) | catalogued as COSV99265772; called by muse, mutect2, varscan2
- ARSF | c.385G>A p.G129R | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100839516; called by muse, mutect2
- ATP8B4 | c.326T>G p.V109G | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99465662; called by muse, mutect2, varscan2
- CDC42BPG | c.3212C>T p.A1071V | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs145094102; called by muse, mutect2, varscan2
- CHAT | c.1189G>T p.E397* | Nonsense Mutation (SNP) | VAF 18/61 reads (30%) | catalogued as COSV100340202; called by muse, mutect2, varscan2
- COG6 | c.863G>A p.G288E | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1282236514, COSV100742930; called by muse, mutect2, varscan2
- DPEP1 | c.754G>A p.V252I | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.88); PolyPhen benign (0.015); catalogued as rs1428445628, COSV55360503; called by muse, mutect2, varscan2
- ELP4 | c.1170G>C p.L390F (on ENST00000350638; = p.L389F on NM_019040.5) | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.377); catalogued as COSV100635183, COSV100635518; called by muse, mutect2, varscan2
- ENDOV | c.236A>G p.Y79C | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs372695550, COSV60497574; called by muse, varscan2
- GABRA6 | c.7T>C p.S3P | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV99194534; called by muse, mutect2, varscan2
- GGT7 | c.1700C>T p.A567V | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.411); catalogued as rs371027305; called by muse, mutect2, varscan2
- GRIP2 | c.1052C>T p.T351M (on ENST00000619221; = p.T254M on NM_001080423.4) | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.061); catalogued as rs763795271, COSV56124863; called by muse, mutect2, varscan2
- GRM3 | c.1323G>A p.T441= | Splice Region (SNP) | VAF 35/148 reads (24%) | catalogued as rs1465764905, COSV100862565; called by muse, mutect2, varscan2
- HNF4A | c.1210G>A p.V404I | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.217); catalogued as rs377151067, CM1310369; called by muse, mutect2, varscan2
- IGHV1-24 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 74/240 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.177); catalogued as rs547711445; called by muse, varscan2
- ISLR2 | c.2055C>A p.D685E | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV100679582; called by muse, mutect2, varscan2
- KCNS3 | c.349T>C p.C117R | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV100411229; called by muse, mutect2, varscan2
- KRT15 | c.1211C>T p.A404V | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV54178540; called by muse, mutect2, varscan2
- LRRC66 | c.830G>A p.W277* | Nonsense Mutation (SNP) | VAF 58/186 reads (31%) | catalogued as COSV100602973; called by muse, mutect2, varscan2
- MGAT5 | c.485G>T p.W162L | Missense Mutation (SNP) | VAF 28/176 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV99924529; called by muse, mutect2, varscan2
- OTOGL | c.2854G>A p.G952R (on ENST00000547103; = p.G943R on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs759133667, COSV72007573; called by muse, mutect2, varscan2
- PDE7A | c.917G>T p.S306I (on ENST00000401827 / NM_001242318.3; = p.S280I on NM_002603.4) | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.082); catalogued as COSV101052668; called by muse, mutect2, varscan2
- PDE7A | c.916A>T p.S306C (on ENST00000401827 / NM_001242318.3; = p.S280C on NM_002603.4) | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.557); catalogued as COSV101052669; called by muse, mutect2, varscan2
- PIK3C2G | c.817A>T p.S273C | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); catalogued as COSV99851735; called by muse, mutect2, varscan2
- PRICKLE3 | c.209G>T p.C70F | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.186); catalogued as COSV99602918; called by muse, mutect2, varscan2
- PSG11 | c.292C>T p.R98* | Nonsense Mutation (SNP) | VAF 82/293 reads (28%) | catalogued as rs375803539; called by muse, mutect2, varscan2
- RAD51B | c.97C>A p.L33I | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.386); catalogued as COSV101185211; called by muse, mutect2, varscan2
- RELL2 | c.19G>A p.D7N | Missense Mutation (SNP) | VAF 69/217 reads (32%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.056); catalogued as rs757296062, COSV99781371; called by muse, mutect2, varscan2
- RNF17 | c.4835C>T p.P1612L | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.232); catalogued as COSV99692820; called by muse, mutect2, varscan2
- RNF213 | c.11051A>G p.E3684G | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV100300645; called by muse, mutect2, varscan2
- RTN1 | c.551A>T p.D184V | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV99955782; called by muse, mutect2, varscan2
- SDR16C5 | c.385G>A p.V129I | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.846); catalogued as rs750792059, COSV58125555; called by muse, mutect2, varscan2
- SHROOM3 | c.2125G>A p.A709T | Missense Mutation (SNP) | VAF 54/169 reads (32%) | SIFT tolerated (0.75); PolyPhen benign (0.019); catalogued as rs781317898, COSV99071385, COSV99934418; called by muse, mutect2, varscan2
- SLC35B4 | c.256C>A p.L86I | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV101043101; called by muse, mutect2
- SMURF2 | c.1774C>G p.R592G | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as COSV52318882, COSV99300725; called by muse, mutect2, varscan2
- SSX5 | c.37G>T p.V13F | Missense Mutation (SNP) | VAF 55/218 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV100308768; called by muse, mutect2, varscan2
- TIMM8A | c.151C>G p.P51A | Missense Mutation (SNP) | VAF 55/182 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.304); catalogued as rs782690796, COSV100437618; called by muse, mutect2, varscan2
- TMEM130 | c.781G>A p.V261M | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.124); catalogued as rs200442119, COSV59558997; called by muse, mutect2, varscan2
- UHRF1BP1L | c.2780A>G p.H927R | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as COSV99691641; called by muse, mutect2, varscan2
- USH2A | c.10691C>A p.S3564* | Nonsense Mutation (SNP) | VAF 20/61 reads (33%) | catalogued as COSV100235299; called by muse, mutect2, varscan2
- WAS | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.379); catalogued as rs868995772, COSV100939497; called by muse, mutect2, varscan2
- ZNF780B | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.476); catalogued as rs199500205; called by muse, mutect2, varscan2
- DSC3 | c.653C>T p.A218V | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.145); called by muse, mutect2
- SPATA16 | c.484_487del p.S162Yfs*16 | Frame Shift Del (DEL) | VAF 25/103 reads (24%) | called by mutect2, pindel, varscan2
- SPATA31A1 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 21/222 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- ABCC12 | c.3172C>T p.L1058= | Silent (SNP) | VAF 36/145 reads (25%) | catalogued as COSV100252731; called by muse, mutect2, varscan2
- ANKEF1 | c.465A>G p.R155= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as rs1429983443, COSV101001024; called by muse, mutect2
- BIN1 | c.291G>A p.R97= | Silent (SNP) | VAF 56/152 reads (37%) | catalogued as rs747940759, COSV99388059; called by muse, mutect2, varscan2
- CDH11 | c.1872C>T p.L624= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV51777180; called by muse, mutect2, varscan2
- CDH7 | c.357G>A p.T119= | Silent (SNP) | VAF 29/81 reads (36%) | catalogued as rs201657602, COSV59881319, COSV59883575; called by muse, mutect2, varscan2
- CROCC | c.2856G>A p.R952= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV65011901; called by muse, mutect2, varscan2
- CYP1A1 | c.231A>C p.R77= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV101122309; called by muse, mutect2, varscan2
- DST | c.13104T>C p.T4368= (on ENST00000361203 / NM_001374722.1; = p.T1956= on NM_015548.5) | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV99756357; called by muse, mutect2, varscan2
- ELMOD1 | c.123T>C p.C41= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as COSV99760061; called by muse, mutect2, varscan2
- EMILIN3 | c.1692T>C p.T564= | Silent (SNP) | VAF 37/148 reads (25%) | catalogued as COSV100182583; called by muse, mutect2, varscan2
- F8 | c.6693C>T p.L2231= | Silent (SNP) | VAF 79/280 reads (28%) | catalogued as COSV100371680; called by muse, mutect2, varscan2
- FAM135B | c.39G>A p.E13= | Silent (SNP) | VAF 29/111 reads (26%) | catalogued as rs367852882; called by muse, mutect2, varscan2
- FAT2 | c.12072G>A p.E4024= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV99942968; called by muse, mutect2, varscan2
- IL17RD | c.1614A>C p.S538= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as COSV99577254; called by muse, mutect2, varscan2
- ITGAX | c.2493C>T p.Y831= | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as rs146985733; called by muse, mutect2, varscan2
- LATS1 | c.2520T>G p.G840= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as COSV99486060; called by muse, mutect2, varscan2
- MEX3B | c.1677C>T p.T559= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as rs1464940004, COSV100314050; called by muse, mutect2, varscan2
- MYOM1 | c.4557C>T p.N1519= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs369162357; called by muse, mutect2, varscan2
- NEFM | c.774C>T p.R258= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as rs1437144686, COSV99647320; called by muse, mutect2, varscan2
- NPAS2 | c.2328G>A p.Q776= | Silent (SNP) | VAF 33/95 reads (35%) | catalogued as COSV100176243; called by muse, mutect2, varscan2
- PDGFRA | c.3201T>A p.I1067= | Silent (SNP) | VAF 34/112 reads (30%) | catalogued as COSV99956641; called by muse, mutect2, varscan2
- PHF8 | c.1497C>T p.A499= (on ENST00000357988 / NM_001184896.1; = p.A463= on NM_015107.3) | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as rs374586083, COSV57682917; called by muse, mutect2, varscan2
- PNKP | c.882G>A p.P294= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs745849196, COSV99681781; called by muse, mutect2, varscan2
- PNPLA2 | c.990G>T p.L330= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV100352064; called by mutect2, varscan2
- PTPN6 | c.591G>A p.T197= | Silent (SNP) | VAF 59/188 reads (31%) | catalogued as rs1324633728, COSV100017117; called by muse, mutect2, varscan2
- RPH3AL | c.912C>T p.D304= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as rs374756503; called by muse, mutect2, varscan2
- RXRA | c.1029C>T p.G343= | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as COSV62685345; called by muse, mutect2, varscan2
- TMEM231 | c.753C>T p.Y251= (on ENST00000258173 / NM_001077418.3; = p.Y280= on NM_001077416.2) | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV99259850; called by muse, mutect2, varscan2
- WWC1 | c.2739G>A p.P913= | Silent (SNP) | VAF 21/178 reads (12%) | catalogued as rs747328142, COSV99515014; called by muse, mutect2, varscan2
- ZFP57 | c.903G>A p.Q301= | Silent (SNP) | VAF 57/162 reads (35%) | catalogued as rs1016766761, COSV100971876, COSV65306160; called by muse, mutect2, varscan2
- MIR380 | n.39G>A | RNA (SNP) | VAF 8/32 reads (25%) | catalogued as rs763781233; called by muse, mutect2, varscan2
